Somatic mutation profile of tumor specimen 0DII4C from CCDI case PBBVRV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.6 years (4,600 days).
Specimen 0DII4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be02e4dd-883d-4b31-9930-8d1df30f311f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII3B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04c57b4f-43d2-4a67-b631-ce0630a90b6b

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 6, Intron 4, 5'UTR 3, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, 5'Flank 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 125/380 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- PDGFRA | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 1181/1612 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- TP53 | c.784_786del p.G262del | In Frame Del (DEL) | VAF 190/378 reads (50%) | hotspot (GDC flag); catalogued as rs1567548347; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 72/324 reads (22%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- ADAMTS7 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 194/473 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66308698; called by muse, mutect2, varscan2
- ATP1B4 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 365/449 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs764760306; called by muse, mutect2, varscan2
- CABLES1 | c.1840G>A p.A614T (on ENST00000256925 / NM_001100619.2; = p.A349T on NM_138375.2) | Missense Mutation (SNP) | VAF 174/535 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as rs757746929; called by muse, mutect2, varscan2
- CASR | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 238/458 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as CM962436; called by muse, mutect2, varscan2
- DIAPH2 | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 205/247 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100230738; called by muse, mutect2, varscan2
- DNAH5 | c.10472C>T p.T3491M | Missense Mutation (SNP) | VAF 313/577 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs760010021; called by muse, mutect2, varscan2
- GABRG1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 200/664 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs142799145, COSV54956004; called by muse, mutect2, varscan2
- GSDMB | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs771584658; called by muse, mutect2, varscan2
- GYS1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781754385; called by muse, mutect2, varscan2
- HDAC4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 299/680 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs375324432; called by muse, mutect2, varscan2
- IL37 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 137/475 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1267548778; called by muse, mutect2, varscan2
- KIF26A | c.2596G>A p.G866R | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs779918856, COSV59466087, COSV59470519; called by muse, mutect2, varscan2
- MYO15A | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 102/408 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs374336846; called by muse, mutect2, varscan2
- MYO7A | c.6161C>T p.P2054L | Missense Mutation (SNP) | VAF 145/507 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1313891142; called by muse, mutect2, varscan2
- NUMA1 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 169/590 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs746636794; called by muse, mutect2, varscan2
- OTOG | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs1290666415; called by muse, mutect2, varscan2
- POLRMT | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 242/661 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs749393748; called by muse, mutect2, varscan2
- PTPRK | c.2972G>T p.G991V (on ENST00000368215 / NM_001291984.2; = p.G992V on NM_002844.4) | Missense Mutation (SNP) | VAF 195/387 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774840923; called by muse, mutect2, varscan2
- SERPINB5 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 276/518 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs372076697, COSV66975490; called by muse, varscan2
- TCHH | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 416/1017 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1206765822, COSV100915597, COSV64278231; called by muse, mutect2, varscan2
- TFAP2D | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 162/310 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as COSV99145938; called by muse, mutect2, varscan2
- USP53 | c.1295_1299del p.L432Sfs*3 | Frame Shift Del (DEL) | VAF 70/105 reads (67%) | catalogued as rs1288933417; called by pindel, varscan2
- ATP6V0A2 | c.377_378del p.I126Rfs*18 | Frame Shift Del (DEL) | VAF 256/714 reads (36%) | called by mutect2, pindel, varscan2
- ATRX | c.4558-1G>A p.X1520_splice | Splice Site (SNP) | VAF 281/348 reads (81%) | called by muse, mutect2, varscan2
- C1S | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 20/439 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2
- CAPN13 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- GABBR1 | c.436A>T p.S146C | Missense Mutation (SNP) | VAF 307/558 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- HCN2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 228/548 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKDCC | c.657C>G p.Y219* | Nonsense Mutation (SNP) | VAF 277/684 reads (40%) | called by muse, mutect2, varscan2
- PLOD2 | c.2038A>G p.N680D | Missense Mutation (SNP) | VAF 304/604 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.395); called by muse, mutect2
- POGK | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC16A10 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 125/418 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ZC3H6 | c.2824_2827del p.N942Efs*5 | Frame Shift Del (DEL) | VAF 104/450 reads (23%) | called by pindel, varscan2
- ZKSCAN4 | c.1445A>C p.E482A | Missense Mutation (SNP) | VAF 124/435 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ADAMTS12 | c.324C>T p.V108= | Silent (SNP) | VAF 15/552 reads (3%) | catalogued as COSV61280402; called by muse, mutect2
- CD1A | c.909C>A p.I303= | Silent (SNP) | VAF 112/594 reads (19%) | called by muse, mutect2, varscan2
- CDHR2 | c.1977C>T p.G659= | Silent (SNP) | VAF 181/531 reads (34%) | called by muse, mutect2, varscan2
- FAM214B | c.1066T>C p.L356= | Silent (SNP) | VAF 211/274 reads (77%) | catalogued as rs141735084; called by muse, mutect2, varscan2
- NBEAL2 | c.630C>T p.L210= | Silent (SNP) | VAF 364/700 reads (52%) | catalogued as rs772969301; called by muse, mutect2, varscan2
- PRKCD | c.1602C>T p.F534= | Silent (SNP) | VAF 230/476 reads (48%) | catalogued as rs79490732, COSV57849035; called by muse, mutect2, varscan2
- CACNA1A | c.5643+49del | Intron (DEL) | VAF 81/188 reads (43%) | catalogued as rs761725528; called by mutect2, varscan2
- CACNG7 | c.*9C>A | 3'UTR (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- CFAP46 | c.3219+50G>C | Intron (SNP) | VAF 65/98 reads (66%) | called by muse, mutect2, varscan2
- CHAC2 | c.-56G>C | 5'UTR (SNP) | VAF 48/301 reads (16%) | catalogued as rs974485124; called by muse, mutect2, varscan2
- CPNE8 | c.799-1572A>G | Intron (SNP) | VAF 196/409 reads (48%) | called by muse, mutect2, varscan2
- GRIA4 | c.-35A>G | 5'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- HECW1 | c.-14C>T | 5'UTR (SNP) | VAF 159/418 reads (38%) | catalogued as rs763752256; called by muse, mutect2, varscan2
- KIF25 | chr6:167996930 G>T | 5'Flank (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- NCBP3 | c.797-60del | Intron (DEL) | VAF 49/96 reads (51%) | catalogued as rs928144295; called by mutect2, varscan2
